Gene-level copy-number profile of tumor specimen MP2PRT-PANUMR-TMP1-A from MP2PRT case MP2PRT-PANUMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,426 days).
Specimen MP2PRT-PANUMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c48fafa-8730-4bc6-bf1e-14c6c44b02cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANUMR-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/78e14589-10ac-4922-a3e2-8cf425eaf127

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 248; copy number 1: 1,673; copy number 2: 55,731; copy number 3: 724.

Homozygous deletions (total copy number 0; autosomes only): 248 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 41 genes (within-gene range 0–2): MALLP2, MIR4436A, IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,114,838–90,115,402, 1 gene (within-gene range 0–1): IGKV3D-15.
- chr2:97,050,729–97,060,415, 2 genes: IGKV2OR2-2, IGKV1OR2-3.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr7:38,256,337–38,256,396, 1 gene (within-gene range 0–1): TRGJP2.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,281,105–22,552,156, 76 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,538,344, 122 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
